Surgical pathology report (de-identified scan), TCGA case TCGA-10-0927, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-10-0927-01A (Primary Tumor).

[page 1 of 2]
SUPPLEMENTAL REPORT

COMMENT:

Immunohistochemistry for HER-2/neu performed by the HercepTest on a section of right ovarian low grade serous carcinoma is negative (0).

This supplemental report is issued to give the results of the immunohistochemical staining; the original diagnoses remain unchanged.

DIAGNOSIS

(A) OMENTUM:

LOW GRADE SEROUS CARCINOMA INVOLVING FIBROADIPOSE TISSUE.

(B) UTERUS, BILATERAL OVARIES AND FALLOPIAN TUBES:

LOW GRADE SEROUS CARCINOMA OF RIGHT OVARY.

LOW GRADE SEROUS CARCINOMA INVOLVING SURFACE OF LEFT OVARY.

LOW GRADE SEROUS CARCINOMA INVOLVING LEFT FALLOPIAN TUBE WITH

DETACHED FRAGMENTS OF CARCINOMA IN RIGHT FALLOPIAN TUBE LUMEN.

Cervix with atrophy.

Atrophic endometrium with adenomyosis.

(C) APPENDIX:

LOW GRADE CARCINOMA INVOLVING APPENDICEAL SEROSA AND MUSCULARIS.

COMMENT

The tumor extensively involves the surfaces of the left and right ovaries; however, the right ovarian parenchymal involvement measures greater than 0.5 cm qualifying as an ovarian primary.

The individual tumor nuclei are atypical, but are uniform, and 7 mitotic figures per 10 high power fields are present.

GROSS DESCRIPTION

(A) OMENTUM - A portion of omentum (19 x 10 x 2.5 cm), infiltrated by a pale tan, mucoid tumor. Representative sections are submitted in A1 through A6.

Source: NCI Genomic Data Commons file c89ffc2e-3dea-4cdd-974c-ccae6490bb25 (TCGA-10-0927.3D93F935-2A93-4987-99C6-0B75E2E59CD3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).